Gene-level copy-number profile of tumor specimen TCGA-G7-6793-01A from TCGA case TCGA-G7-6793, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 60.8 years (22,215 days).
Specimen TCGA-G7-6793-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.879bb2d6-ef98-4384-99e5-83afab87e987.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G7-6793-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1daecc41-ab4f-4a46-9a7e-58d163a0dacb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 12,787; copy number 2: 42,246; copy number 3: 2,897; copy number 4: 1,469; copy number 5: 209; copy number 6: 143; copy number 7: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G7-6793-01A-11D-1959-01): tumor purity 0.62, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:239,898,016–241,484,995, 32 genes: CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8, RGS7, RFKP1, HNRNPA1P42, AL590682.1, MIR3123, AL592076.1, AL359764.1, AL359764.2, AL359764.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 382 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:98,147,479–98,660,570, 24 genes, copy number 5: OR5H14, OR5H15, OR5H5P, OR5H3P, OR5H4P, AC117473.1, OR5H7P, OR5H6, OR5H2, OR5H8, OR5K4, OR5K3, UBFD1P1, OR5K1, OR5K2, CLDND1, AC021660.3, AC021660.2, RPL38P4, GPR15, AC021660.4, CPOX, AC021660.1, WWP1P1.
- chr3:117,544,205–123,585,053, 113 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr3:126,660,609–127,288,046, 13 genes, copy number 5: NUP210P1, AC078867.1, CHCHD6, RCC2P4, AC011199.1, PLXNA1, AC112482.2, C3orf56, Y_RNA, AC112482.1, RNU6-1047P, AC133681.1, PRR20G.
- chr3:128,693,669–130,035,539, 58 genes, copy number 5 (within-gene range 3–5): RAB7A, AC079945.1, MARK2P8, FTH1P4, RN7SL698P, RPS15AP16, MARK2P17, MARK3P3, MARK2P6, AC112484.3, AC112484.1, AC112484.2, AC112484.5, ACAD9, CFAP92, AC112484.4, EFCC1, AC108673.1, GP9, RAB43, ISY1-RAB43, AC108673.2, ISY1, AC108673.3, CNBP, RPS27P12, COPG1, MIR6826, AC137695.3, HMCES, H1-10, H1-10-AS1, NUP210P3, AC137695.1, AC137695.2, AL449212.1, RPL32P3, SNORA7B, EFCAB12, MBD4, IFT122, RHO, H1-8, PLXND1, RN7SL752P, AC023162.1, TMCC1, RNY3P13, U6, AC083799.1, TMCC1-AS1, AC083906.3, TRH, AC083906.1, AC083906.5, AC083906.2, OR7E129P, OR7E21P.
- chr3:139,389,761–141,865,279, 44 genes, copy number 5–7 (within-gene range 4–7): AC046134.2, RBP2, AC097103.1, ACTG1P1, RBP1, NMNAT3, AC046134.1, RN7SKP124, RN7SL724P, AC110716.2, AC110716.1, AC016933.1, TRMT112P5, CLSTN2, AC010181.1, AC010181.2, CLSTN2-AS1, AC048346.1, TRIM42, AC121333.1, RPL23AP41, SLC25A36, AC108727.1, SPSB4, AC108727.2, PXYLP1, AC022215.2, AC022215.1, AC117383.1, AC117383.2, ZBTB38, AC010184.1, KRT18P35, RASA2, RASA2-IT1, YWHAQP6, LINC02618, TPT1P3, AC112771.1, RNF7, AC112504.2, GRK7, AC112504.3, HMGN2P25.
- chr3:167,864,773–174,378,005, 106 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr3:182,793,503–183,684,519, 21 genes, copy number 6 (within-gene range 3–6): ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1, MCCC1, MCCC1-AS1, LAMP3, MCF2L2, B3GNT5, RNA5SP151, LINC00888, SNORA63D, AC092960.2, SNORA63E, AC092960.1, AC092960.3, KLHL6, KLHL6-AS1, AC068769.1, KLHL24.
- chr3:197,445,061–197,467,105, 3 genes, copy number 6: AC128709.2, AC128709.1, AC128709.3.

Autosomal genes at a single copy (total copy number 1): 12,784. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
